HCMI case HCM-EXPT-0580-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3762208b-fe46-400d-bec8-dd0301d5675d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1947.

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 72.3 years (26,419 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Distant Nodes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Neoadjuvant.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Follow-up contact recording only the day: day 223.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- CD274 (IHC): Negative.
- EGFR: Negative.
- KRAS mutation, nos: Positive; Amino-acid change: p.Gln61His.
- MET: Negative.
- RET rearrangement: Negative.
- ROS1 rearrangement (FISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 172.7 cm; BMI: 23.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 80; Tobacco smoking quit year: 2011.
- Exposure type: Asbestos.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-0580-C34-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-0580-C34-06A-01-S1-HE: Section location: Top; Percent tumor cells: 27; Percent tumor nuclei: 70; Percent normal cells: 14; Percent necrosis: 1; Percent stromal cells: 58; Percent lymphocyte infiltration: 13; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-0580-C34-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 26; Percent tumor nuclei: 35; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 74; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
